Somatic mutation profile of tumor specimen TCGA-24-1418-01A (aliquot TCGA-24-1418-01A-01W-0549-09) from TCGA case TCGA-24-1418, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.0 years (24,842 days).
Specimen TCGA-24-1418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd36e30c-2a5d-4467-b74d-6fc2d9828165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1418-10A (Blood Derived Normal), aliquot TCGA-24-1418-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c59042e-cb15-4785-a827-271b7c023a1a

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 48, Silent 13, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.681dup p.D228* | Frame Shift Ins (INS) | VAF 66/103 reads (64%) | catalogued as rs1567550002; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM29 | c.1183T>G p.F395V | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100822277; called by muse, mutect2
- ADGRF5 | c.4007A>G p.E1336G | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99346527; called by muse, mutect2
- AL136295.1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99938338; called by muse, mutect2
- ANK3 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55078131; called by muse, mutect2, varscan2
- ARHGEF9 | c.473T>A p.F158Y | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53643173; called by muse, mutect2, varscan2
- BOD1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53633087; called by muse, mutect2, varscan2
- CATSPERD | c.1726G>A p.V576I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs374184519; called by muse, mutect2, varscan2
- CHRNA7 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs547741252, COSV100181814; called by muse, mutect2, varscan2
- COL19A1 | c.1044A>T p.K348N | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV59585283; called by muse, mutect2, varscan2
- DNA2 | c.2420A>T p.E807V | Missense Mutation (SNP) | VAF 151/289 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV64429944; called by muse, mutect2, varscan2
- DPPA5 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV100951532; called by muse, mutect2
- DTX3L | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 107/538 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56143749, COSV56145338; called by muse, mutect2, varscan2
- DUSP22 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV60529907, COSV60530704; called by muse, mutect2, varscan2
- FAM111A | c.1193G>C p.S398T | Missense Mutation (SNP) | VAF 145/221 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV64655319; called by muse, mutect2, varscan2
- GDA | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.25); catalogued as COSV52996994; called by muse, mutect2, varscan2
- GOSR2 | c.32C>T p.S11F (on ENST00000393456 / NM_001321134.1; = p.S29F on NM_004287.5) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV99846316; called by muse, mutect2
- HORMAD1 | c.765G>C p.R255S | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59272956; called by muse, mutect2, varscan2
- KCNS3 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 103/406 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150320186; called by muse, mutect2, varscan2
- KIF18A | c.2146A>T p.N716Y | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV54187064; called by muse, mutect2, varscan2
- KLHL9 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.539); catalogued as COSV62922371; called by muse, mutect2, varscan2
- KRT23 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV52926976; called by muse, mutect2, varscan2
- MARF1 | c.4736C>G p.P1579R | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as COSV100706429; called by muse, mutect2
- MECR | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV55287208; called by muse, mutect2, varscan2
- MED25 | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs775239238, COSV57206921; called by muse, varscan2
- MTMR11 | c.1600G>T p.G534C (on ENST00000439741 / NM_001145862.2; = p.G462C on NM_181873.3) | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99641462; called by muse, mutect2
- MUSK | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV51887794, COSV51894714; called by muse, mutect2, varscan2
- MYBL1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101576614, COSV101576616; called by muse, mutect2
- MYH15 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 57/668 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779771539, COSV99844435; called by muse, mutect2
- MYO3A | c.3860C>A p.P1287H | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as CM1411120, COSV56345984; called by muse, mutect2, varscan2
- N4BP1 | c.1343A>G p.K448R | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52212918; called by muse, mutect2, varscan2
- NALCN | c.924C>A p.F308L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV51944037, COSV99214745; called by muse, mutect2
- OR8A1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as COSV52510166; called by muse, mutect2, varscan2
- PARN | c.1284G>C p.M428I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV58370297; called by muse, mutect2, varscan2
- PEAK1 | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433488; called by muse, mutect2
- PEG3 | c.4430G>T p.G1477V | Missense Mutation (SNP) | VAF 103/368 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV55638281, COSV55645110; called by muse, mutect2, varscan2
- PPIP5K2 | c.2371C>T p.Q791* | Nonsense Mutation (SNP) | VAF 5/146 reads (3%) | catalogued as COSV100384318; called by muse, mutect2
- PTCHD1 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as rs150912089, COSV65062451; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PTPRN2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs777411785, COSV67043865, COSV67061765; called by muse, mutect2, varscan2
- RGS18 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66509790; called by muse, varscan2
- RIC8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62696804; called by muse, mutect2, varscan2
- SETX | c.4396G>T p.G1466C | Missense Mutation (SNP) | VAF 238/628 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV56393344; called by muse, mutect2, varscan2
- SH3PXD2B | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as COSV61125373, COSV61129643; called by muse, mutect2, varscan2
- SI | c.4669A>C p.N1557H | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100017380; called by muse, mutect2
- TENM2 | c.1055T>C p.L352P (on ENST00000518659 / NM_001122679.2; = p.L161P on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319478; called by muse, mutect2
- TEX14 | c.730G>C p.A244P (on ENST00000240361 / NM_001201457.2; = p.A238P on NM_031272.5) | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV53617962, COSV53625034, COSV99543805; called by muse, mutect2
- TMEM174 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57114237; called by muse, mutect2, varscan2
- TRAK1 | c.968C>G p.T323R (on ENST00000327628 / NM_001349247.2; = p.T265R on NM_014965.5) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV58263501; called by muse, mutect2, varscan2
- TRDN | c.326T>A p.L109* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV62131233; called by muse, mutect2, varscan2
- UNC5CL | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.162); catalogued as COSV55112451; called by muse, mutect2
- WDR5B | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58073027; called by muse, mutect2, varscan2
- SECISBP2 | c.910del p.V304Ffs*19 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- TRAV13-1 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.108); called by muse, mutect2
- CACNA1C | c.1179C>A p.S393= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV59762934; called by muse, mutect2, varscan2
- CCDC141 | c.2877G>A p.R959= | Silent (SNP) | VAF 48/235 reads (20%) | catalogued as COSV55369493; called by muse, mutect2, varscan2
- CDCP2 | c.444C>A p.V148= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100313719, COSV61283529; called by muse, mutect2
- CLDN18 | c.238C>A p.R80= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV51736198, COSV51737856; called by muse, mutect2, varscan2
- ELN | c.1452C>T p.G484= | Silent (SNP) | VAF 10/221 reads (5%) | catalogued as rs1301967913, COSV99333269; called by muse, mutect2
- FLG | c.447G>A p.G149= | Silent (SNP) | VAF 75/205 reads (37%) | catalogued as rs765072283, COSV64237488; called by muse, mutect2, varscan2
- ITGA4 | c.1239C>T p.T413= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV99276881; called by muse, mutect2
- KIT | c.2664G>A p.R888= | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as COSV55418358; called by muse, mutect2, varscan2
- KLHL9 | c.528C>T p.F176= | Silent (SNP) | VAF 23/191 reads (12%) | catalogued as COSV62922461; called by muse, mutect2, varscan2
- LHX8 | c.336C>T p.H112= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99634513; called by muse, mutect2
- PCDHA3 | c.1356G>A p.A452= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs782349098, COSV63538912; called by muse, mutect2
- RSPO2 | c.687G>A p.Q229= | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as rs1335821459, COSV99410518; called by muse, mutect2
- TXNIP | c.504T>A p.V168= | Silent (SNP) | VAF 121/1164 reads (10%) | catalogued as COSV65221293; called by muse, mutect2, varscan2
